Somatic mutation profile of tumor specimen TCGA-12-0827-01A (aliquot TCGA-12-0827-01A-01W-0424-08) from TCGA case TCGA-12-0827, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 38.6 years (14,093 days).
Specimen TCGA-12-0827-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 60d7f6bf-4983-4cf5-bcd1-222500f4bf79.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-12-0827-10A (Blood Derived Normal), aliquot TCGA-12-0827-10A-01W-0424-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dd603750-0393-4824-a240-8ed0747a72ef

The open-access MAF lists 34 somatic variants for this specimen: 27 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 22, Silent 7, Frame Shift Ins 2, Frame Shift Del 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 377/1241 reads (30%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- BRPF3 | c.1427T>C p.V476A | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.081); catalogued as COSV100326045; called by muse, mutect2, varscan2
- CEP250 | c.6524A>G p.D2175G | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as COSV100699078; called by muse, mutect2, varscan2
- COL7A1 | c.2065G>T p.V689L | Missense Mutation (SNP) | VAF 16/229 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV60396610; called by muse, mutect2
- CTBP1 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs868779152, COSV99337959; called by muse, mutect2, varscan2
- EIPR1 | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 9/115 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as COSV101182226; called by muse, mutect2
- ENDOD1 | c.457G>A p.V153I | Missense Mutation (SNP) | VAF 42/270 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV99566689; called by muse, mutect2, varscan2
- FCRL5 | c.1029C>G p.F343L | Missense Mutation (SNP) | VAF 30/1050 reads (3%) | SIFT tolerated (0.74); PolyPhen benign (0.022); catalogued as COSV100709149; called by muse, mutect2
- FLNA | c.5882C>T p.S1961F (on ENST00000369850 / NM_001110556.2; = p.S1953F on NM_001456.3) | Missense Mutation (SNP) | VAF 74/217 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100774957; called by muse, mutect2, varscan2
- GABBR1 | c.1196A>G p.N399S | Missense Mutation (SNP) | VAF 201/1468 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.764); catalogued as COSV100589907; called by muse, mutect2, varscan2
- KCNH3 | c.2522T>C p.F841S | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV99235547; called by muse, mutect2, varscan2
- LAMA1 | c.4466A>G p.E1489G | Missense Mutation (SNP) | VAF 56/153 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101057105; called by muse, mutect2, varscan2
- LAMB2 | c.4882dup p.A1628Gfs*4 | Frame Shift Ins (INS) | VAF 12/124 reads (10%) | catalogued as rs747602505; called by mutect2, varscan2
- LMO7 | c.3787-1G>A p.X1263_splice (on ENST00000357063; = p.X944_splice on NM_005358.5) | Splice Site (SNP) | VAF 298/599 reads (50%) | catalogued as COSV100413663; called by muse, mutect2, varscan2
- LPAR2 | c.910C>A p.R304S | Missense Mutation (SNP) | VAF 28/508 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as COSV101345509; called by muse, mutect2
- MYOF | c.5467G>T p.G1823C | Missense Mutation (SNP) | VAF 11/180 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100825925; called by muse, mutect2
- OGT | c.585T>G p.S195R | Missense Mutation (SNP) | VAF 410/1256 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101035548, COSV65480605; called by muse, varscan2
- OR7A17 | c.626G>T p.G209V | Missense Mutation (SNP) | VAF 14/225 reads (6%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.143); catalogued as rs1415261528, COSV100541644; called by muse, mutect2
- PCNX1 | c.1633A>G p.K545E | Missense Mutation (SNP) | VAF 36/396 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.031); catalogued as COSV99456576; called by muse, mutect2
- PDE11A | c.2389G>A p.D797N | Missense Mutation (SNP) | VAF 10/203 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1310336399, COSV99613884; called by muse, mutect2
- PHF19 | c.784G>A p.D262N | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); catalogued as COSV100384359; called by muse, mutect2, varscan2
- SCUBE1 | c.2644A>G p.T882A | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1044318456, COSV100683519; called by muse, mutect2, varscan2
- WDR38 | c.751G>A p.A251T | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.027); catalogued as rs201585509; called by muse, mutect2, varscan2
- KCNMA1 | c.771dup p.V258Rfs*36 | Frame Shift Ins (INS) | VAF 6/41 reads (15%) | called by mutect2, pindel
- LMF2 | c.1596del p.K533Rfs*4 | Frame Shift Del (DEL) | VAF 13/42 reads (31%) | called by mutect2, pindel
- PRAMEF6 | c.1350G>T p.R450S | Missense Mutation (SNP) | VAF 246/1362 reads (18%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.944); called by muse, varscan2
- TP53 | c.437_448delinsCAACC p.W146Sfs*22 | Frame Shift Del (DEL) | VAF 65/310 reads (21%) | called by pindel, varscan2*
- AKAP4 | c.777G>A p.E259= | Silent (SNP) | VAF 446/2097 reads (21%) | catalogued as COSV100654320; called by muse, mutect2, varscan2
- CENPF | c.6349C>T p.L2117= | Silent (SNP) | VAF 48/557 reads (9%) | catalogued as COSV100871833; called by muse, mutect2
- COL5A2 | c.3921G>A p.Q1307= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV66412427; called by muse, mutect2, varscan2
- IL12RB1 | c.1164G>A p.P388= | Silent (SNP) | VAF 132/300 reads (44%) | catalogued as rs761031233, COSV100443143; called by muse, mutect2, varscan2
- ODF2 | c.84C>T p.V28= (on ENST00000434106 / NM_153433.2; = p.V72= on NM_153432.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 36/192 reads (19%) | catalogued as COSV100654834, COSV100654862; called by muse, mutect2, varscan2
- SBNO2 | c.1395C>T p.I465= | Silent (SNP) | VAF 99/139 reads (71%) | catalogued as rs1303933236, COSV100684837; called by muse, mutect2, varscan2
- USP17L2 | c.957C>G p.L319= | Silent (SNP) | VAF 5/33 reads (15%) | called by mutect2, varscan2
